Somatic mutation profile of tumor specimen ASCProject_0076_T1_WES (aliquot ASCProject_0076_T1_WES_1) from CMI case ASCProject_0076, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.7 years (18,886 days).
Specimen ASCProject_0076_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21a1600f-b851-4dd8-aa0e-593999258bf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0076_SALIVA (Saliva), aliquot ASCProject_0076_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2da0c961-7fc6-4c60-9c26-79ad6468ae55

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, 5'UTR 2, Frame Shift Del 1, 3'UTR 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EHD2 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV54411034; called by muse, mutect2
- EPHA5 | c.2861A>T p.N954I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV56657242; called by muse, mutect2, varscan2
- GPR119 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 17/368 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1193702029; called by muse, mutect2
- MBD1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 75/496 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1462113864, COSV54008712; called by muse, varscan2
- NCAPH | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs571328297, COSV99545724; called by muse, mutect2, varscan2
- OPRM1 | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.281); catalogued as COSV57672571, COSV57682616; called by muse, mutect2
- POLR3D | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs1126676; called by muse, mutect2, varscan2
- ABCA13 | c.995A>G p.H332R | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- ABHD13 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BUB1 | c.567G>C p.Q189H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, varscan2
- KLHL32 | c.1335T>A p.D445E | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.833); called by muse, mutect2
- MAP3K3 | c.779-3C>G | Splice Region (SNP) | VAF 38/480 reads (8%) | called by muse, mutect2
- NLGN3 | c.1399C>T p.P467S (on ENST00000358741 / NM_181303.2; = p.P447S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- P2RY1 | c.442C>A p.H148N | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TATDN3 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBC1D8 | c.3389A>G p.Q1130R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by mutect2, varscan2
- TSPYL6 | c.214del p.H72Tfs*19 | Frame Shift Del (DEL) | VAF 31/245 reads (13%) | called by mutect2, pindel, varscan2
- UNC13C | c.1265C>A p.P422Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.174); called by mutect2, varscan2
- CSMD3 | c.4341A>G p.V1447= (on ENST00000297405 / NM_001363185.1; = p.V1343= on NM_052900.3) | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV52243873; called by muse, mutect2, varscan2
- DNAI2 | c.1194G>A p.S398= | Silent (SNP) | VAF 41/234 reads (18%) | catalogued as rs556547267, COSV100210064; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EYA2 | c.723G>A p.P241= | Silent (SNP) | VAF 49/375 reads (13%) | catalogued as rs892426959; called by muse, mutect2, varscan2
- INSYN2B | c.1002C>T p.N334= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- RBMXL2 | c.645G>A p.S215= | Silent (SNP) | VAF 24/218 reads (11%) | catalogued as COSV60981811; called by muse, mutect2, varscan2
- RGS14 | c.1686C>G p.T562= | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, varscan2
- FAM3A | c.-30G>A | 5'UTR (SNP) | VAF 61/422 reads (14%) | catalogued as rs782268663; called by muse, mutect2, varscan2
- IGKV4-1 | c.-77C>T | 5'UTR (SNP) | VAF 30/238 reads (13%) | catalogued as rs1327561206; called by muse, mutect2, varscan2
- UMPS | c.*4114A>G | 3'UTR (SNP) | VAF 10/143 reads (7%) | catalogued as rs1202621240; called by muse, mutect2
